Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98J, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98J-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

ICD O-3
Mesothelioma, epithelioid
malignant 905213
Site @ Pleura NOS
C88.4
J10 3/12/14

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. #7 lymph node; biopsy:

- One anthracotic lymph node, no tumor (0/1).

B. #8 lymph node; biopsy:

- Six anthracotic lymph nodes, no tumor (0/6).

C. #9 lymph node; biopsy:

- Three anthracotic lymph nodes, no tumor (0/3).

D. 4R lymph node; biopsy:

- One of eight lymph nodes positive for metastatic tumor (1/8).

E. Right pleura, diaphragm, pericardium; resection:

- Malignant mesothelioma, epithelial type. See parameters and comment

- Four of twenty-four lymph nodes positive for metastatic mesothelioma.

Thoracic Mesothelioma Pathologic Parameters

Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural and pericardial resection

Tumor Site: Right pleura

Tumor Configuration and Size: Diffuse, Maximum thickness: 1.7 cm

MICROSCOPIC

Histologic Type: Epithelioid (epithelial) mesothelioma (60% tubular, 20% trabecular, 10% micropapillary, 10% solid)

Tumor Extension:

Confluent visceral pleural tumor (including fissure)

[page 2 of 4]
Into but not through diaphragm
Lung parenchyma (E10-11)
Into mediastinal fat (E1-E2)
Into but not through the pericardium (E1-E2)
Venous/Lymphatic (Large/Small Vessel) Invasion: Present
Margins: Cannot be assessed

***Pathologic Staging (pTNM): pT3, N2**

pT3: Tumor (locally advanced but potentially resectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: invasion of the endothoracic fascia, invasion into mediastinal fat, solitary completely resectable focus of tumor invading the soft tissues of the chest wall, non-transmural involvement of the pericardium

Regional Lymph Nodes (pN)

pN2: Metastases in the subcarinal lymph node(s) and/or the ipsilateral internal mammary or mediastinal lymph node(s)
Specify: Number examined: 24
Number involved: 4

***Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).**

Comment

Immunohistochemistry for WT-1 (+ve), Calretinin (+ve), MOC31 (-ve) and BG8 (-ve) confirms the diagnosis of malignant mesothelioma (block E7, controls appropriate).

xxx

☐ M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ M.D.

Electronically Signed Out by ☐, M.D.

Clinical History:

The patient is a male with no a malignant pleural mesothelioma of the right pleural space who undergoes a right thoracotomy parietal pleurectomy and decortication.

Specimens Received:

A: #7 lymph node

[page 3 of 4]
B: #8 lymph node
C: #9 lymph node
D: 4R lymph node
E: Pleura, diaphragm, pericardium

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "#7 lymph node". Received fresh and placed in formalin is an unoriented 2.8 x 1.5 x 0.8 cm portion of gray-brown rubbery tissue with a small amount of attached lobulated yellow adipose. The specimen is bisected and entirely submitted as A1-A2.

B. The second container is additionally identified as, "#8 lymph node". Received fresh and placed in formalin is a 4.3 x 2.5 x 0.5 cm portion of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 6 gray-black apparent lymph nodes ranging from 0.2-1.2 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

B1: 3 lymph nodes

B2: 2 lymph nodes

B3: largest lymph node, bisected

C. The third container is additionally identified as, "#9 lymph node". Received fresh and placed in formalin is a 2 x 1.2 x 0.5 cm unoriented portion of lobulated yellow fibrofatty tissue. The specimen is sectioned revealing 2 gray-black rubbery apparent lymph nodes measuring 0.6 and 0.8 cm in greatest dimension. The specimen is entirely submitted as C1.

D. The fourth container is additionally identified as, "4R". Received fresh and placed in formalin is a 3 x 2.3 x 0.8 cm portion of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 8 apparent tan to gray-black rubbery lymph nodes ranging from 0.2-1 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

D1-D2: 3 lymph nodes in each cassette

D3: 2 lymph nodes

E. The fifth container is additionally identified as, "5. Pleura, diaphragm and pericardium". Received fresh and placed in formalin is a 629.5 g, 34.5 x 25 x 3 cm portion of visceral pleura with attached 7 x 6.5 cm glistening pink-gray membranous tissue designated pericardium (marked by a black suture) and attached 22.8 x 15 cm portion of diaphragm (marked by white suture). The specimen has an overall volume of approximately 700 cc. The pericardium is smooth, glistening and is inked blue. Adjacent to the pericardium is 8.5 x 6.5 x 2.5 cm area of abundant yellow fibrofatty tissue in which multiple apparent tan to gray-black rubbery lymph nodes ranging from 0.3-1.5 cm in greatest dimension are

[page 4 of 4]
identified. Sectioning through the pericardium reveals patchy ill-defined gray-tan nodules ranging from 0.5-1.7 cm in greatest dimension which focally abut the inked surface. The inner aspect of the specimen displays patchy areas of visceral pleura measuring up to 7 x 6.7 cm. The superior inner aspect of the specimen is covered by patchy gray-tan firm nodules ranging from 0.2-1.5 cm in greatest dimension. The diaphragm is inked green. The diaphragm is diffusely covered by a grey-tan firm plaque ranges from 0.5-1.7 cm in thickness. Upon sectioning, the plaque focally invades into the diaphragm muscle extending to within 0.3 cm of the inked surface. Gross photographs are taken. Representative sections are submitted as follows:

E1-E2: pericardium

E3-E4: sections of plaque and diaphragm, deepest invasion

E5-E7: additional sections of plaque and diaphragm

E8-E17: sections from remainder of specimen

E18-E19: 4 lymph nodes in each cassette

E20: one apparent lymph node, bisected

xxx

[]

Dual/Synchronous Primary Noted	QUALIFIED	DISQUALIFIED

Source: NCI Genomic Data Commons file 5ee75981-99c1-456a-878c-52f26f6434e9 (TCGA-3U-A98J.B8F92EDC-3074-4BAA-99AA-B62741D65285.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).